TCGA case TCGA-BR-6456 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ca3c5e0-32b0-4467-8ec0-ca212e35d2b3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 74 years; Vital status: Dead; Days to death: 526 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 74.7 years (27,288 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 526 days (1.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 4.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 308 days; Disease response: Tumor Free.
- Days to follow up: 526 days (1.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-6456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.3; Shortest dimension: 0.5.
  Slide TCGA-BR-6456-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BR-6456-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BR-6456-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-6456-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BR-6456-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 2; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Tver.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Cause of death: Other, non-malignant disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 526 days; disease-specific survival: no event (censored), 526 days; disease-free interval: no event (censored), 526 days; progression-free interval: no event (censored), 526 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-6456-01A-11D-1799-01): tumor purity 0.3, ploidy 3.56, whole-genome doublings 1.
